Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6L4, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6L4-01A (Primary Tumor).

[page 1 of 2]
ICD-9-3
Adenocarcinoma NOS 8140/3
Site Distal third esophagus
C155
QW 6/25/13

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) STOMACH, CARDIA, BIOPSY:

Cardio-xyntic mucosa with mild inactive chronic inflammation and reactive epithelial changes; negative for tumor, intestinal metaplasia, and *Helicobacter pylori* (H&E).

(B) ESOPHAGUS, DISTAL AT 34-35 CM, BIOPSY:

Squamous mucosa with no diagnostic abnormality.

(C) ESOPHAGUS, DISTAL MASS, BIOPSY:

INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH OVERLYING SQUAMOUS MUCOSA.

GROSS DESCRIPTION

(A) CARDIA - Four tan-brown soft tissue fragments, 0.3 - 0.4 cm. The specimen is submitted in A.

(B) DISTAL ESOPHAGUS 34-35 CM - Four tan-gray soft tissue fragments, 0.3 - 0.5 cm. The specimen is submitted in B.

(C) DISTAL ESOPHAGEAL MASS - Five tan-red soft tissue fragments, 0.3 - 0.4 cm. The specimen is submitted in C.

CLINICAL HISTORY

Distal esophageal cancer.

SNOMED CODES

T-56000, T-57000, M-81403, M-43000

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 2]
Page: 2
Specimen Date/Time:

ADDENDUM

This modified report is being issued to report IHC studies

ADDENDUM

This modified report is being issued to report immunohistochemistry studies.

Addendum completed by

COMMENT

By immunohistochemistry, tumor cells are negative for Her-2/neu (score 0 out 3).

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 6010074b-6794-4ae2-aa86-05e39e93963d (TCGA-R6-A6L4.0C4695E1-57E8-4E79-AD72-FDC74828089D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).